Somatic mutation profile of tumor specimen C3L-00967-04 (aliquot CPT0101530009) from CPTAC case C3L-00967, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.8 years (25,489 days).
Specimen C3L-00967-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce949d94-644e-4bdb-b0c4-aabe7fd10a92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00967-31 (Blood Derived Normal), aliquot CPT0100970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/774e0b4f-6fce-442d-a1da-8fd806600f27

The open-access MAF lists 138 somatic variants for this specimen: 85 protein-altering or splice-affecting, 40 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 40, Nonsense Mutation 7, 3'UTR 6, Intron 5, Frame Shift Ins 4, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs375152706; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 119/465 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs672601346, CM099131, COSV65420631; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 185/472 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACAN | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs761237568; called by muse, mutect2
- ACVRL1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766559713, COSV101187959, COSV66360420; called by muse, mutect2
- AHCY | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.074); catalogued as rs756833799; called by muse, mutect2, varscan2
- AHNAK2 | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 128/652 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60908483, COSV60908616; called by muse, varscan2
- BHLHE22 | c.596dup p.L200Pfs*9 | Frame Shift Ins (INS) | VAF 84/620 reads (14%) | catalogued as rs1380139019; called by mutect2, varscan2
- BNC2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 99/350 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66146162; called by muse, mutect2, varscan2
- CHST11 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.131); catalogued as rs139158533; called by muse, mutect2, varscan2
- COL5A2 | c.3491G>A p.G1164E | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223508, COSV66407271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP24A1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 59/522 reads (11%) | catalogued as rs768752896; called by muse, mutect2, varscan2
- DACH1 | c.1564C>T p.R522W (on ENST00000619232 / NM_001366712.1; = p.R470W on NM_080759.6) | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as rs767327632; called by muse, mutect2, varscan2
- EGFL6 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV63634551; called by muse, mutect2, varscan2
- FAM187A | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298181731; called by muse, mutect2, varscan2
- FMN2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 247/609 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60420267; called by muse, mutect2, varscan2
- FREM2 | c.3184G>A p.V1062I | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs773833901; called by muse, mutect2, varscan2
- IGSF9 | c.2005G>T p.V669L (on ENST00000368094 / NM_001135050.2; = p.V653L on NM_020789.4) | Missense Mutation (SNP) | VAF 105/744 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV63642295; called by muse, mutect2, varscan2
- INHBA | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 192/441 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54222628; called by muse, mutect2, varscan2
- JAKMIP1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs531474378, COSV51545488; called by muse, mutect2, varscan2
- KIAA0232 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330326733; called by muse, mutect2, varscan2
- KRT77 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1195405886; called by muse, mutect2, varscan2
- KSR2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 110/537 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs765751335; called by muse, mutect2, varscan2
- MAGEC1 | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs912000082; called by muse, mutect2
- MED12L | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 107/474 reads (23%) | catalogued as rs758266947, COSV99854041; called by muse, mutect2, varscan2
- MROH2B | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101270456, COSV68181433; called by muse, mutect2, varscan2
- MSR1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 34/318 reads (11%) | catalogued as COSV50540000; called by muse, mutect2, varscan2
- NONO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV52137317, COSV52141002; called by muse, mutect2, varscan2
- OBSCN | c.18460T>A p.F6154I | Missense Mutation (SNP) | VAF 263/654 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs751208731; called by muse, mutect2, varscan2
- OR56A3 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 124/481 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61568855; called by muse, mutect2, varscan2
- OR5P2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV61490987; called by muse, mutect2, varscan2
- PAK3 | c.1391G>A p.G464E (on ENST00000262836 / NM_001324328.2; = p.G449E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53273478; called by muse, mutect2, varscan2
- PAMR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 66/297 reads (22%) | catalogued as rs757758192, COSV53512436; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by muse, mutect2, varscan2
- PKHD1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as rs1382326473; called by muse, mutect2, varscan2
- PLCL1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs751215339, COSV101407257; called by muse, mutect2, varscan2
- PRKDC | c.4564G>A p.G1522R | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1252211634; called by muse, mutect2, varscan2
- PRRC2B | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as rs1420111570; called by muse, mutect2, varscan2
- SAMD3 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs1273316288; called by muse, mutect2, varscan2
- SEZ6L | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 225/616 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.502); catalogued as COSV50671375; called by muse, mutect2, varscan2
- SIPA1L2 | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 270/657 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1424892562; called by muse, mutect2, varscan2
- SLC9A4 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 74/444 reads (17%) | catalogued as rs571221714, COSV54834023; called by muse, mutect2, varscan2
- TDRD1 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52587364; called by muse, mutect2, varscan2
- TRIM58 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 299/713 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as COSV63568958, COSV63570445; called by muse, mutect2, varscan2
- ZFHX2 | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 81/455 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.201); catalogued as COSV70219672; called by muse, mutect2, varscan2
- ZFHX4 | c.5669C>T p.S1890F | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51468908, COSV51480339, COSV99269107; called by muse, mutect2, varscan2
- ZNF879 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs774868271; called by muse, mutect2, varscan2
- ABCA13 | c.12354G>T p.K4118N | Missense Mutation (SNP) | VAF 142/511 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ABCC10 | c.3997T>C p.F1333L (on ENST00000372530 / NM_001198934.2; = p.F1305L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/454 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTA1 | c.1061dup p.Q355Pfs*46 | Frame Shift Ins (INS) | VAF 77/644 reads (12%) | called by mutect2, pindel, varscan2
- ALPK2 | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 129/666 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- CACNA1H | c.6745G>A p.E2249K | Missense Mutation (SNP) | VAF 159/622 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC188 | c.308G>A p.W103* | Nonsense Mutation (SNP) | VAF 105/609 reads (17%) | called by muse, mutect2, varscan2
- CFAP47 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 147/377 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTAGE15 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2
- DOLK | c.1270A>T p.R424* | Nonsense Mutation (SNP) | VAF 95/433 reads (22%) | called by muse, mutect2, varscan2
- DUOX2 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- F11 | c.577T>G p.C193G | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXP2 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- HELZ2 | c.2267A>T p.H756L (on ENST00000467148 / NM_001037335.2; = p.H187L on NM_033405.3) | Missense Mutation (SNP) | VAF 33/792 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- HHATL | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPGD | c.499-2_500dup p.A168Vfs*4 | Frame Shift Ins (INS) | VAF 34/238 reads (14%) | called by mutect2, pindel, varscan2
- HROB | c.1774-1G>A p.X592_splice | Splice Site (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- INTS2 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARK2 | c.1945T>G p.F649V | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MUC2 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MYH4 | c.1738T>A p.F580I | Missense Mutation (SNP) | VAF 104/498 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR6N1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 111/667 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PABPC5 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBAK | c.1313T>A p.F438Y | Missense Mutation (SNP) | VAF 68/482 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SAMD9L | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SH3GL3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SIM1 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2
- SIPA1L1 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC34A2 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SLC4A10 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPATA31D1 | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 91/492 reads (18%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SPRR2G | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 118/439 reads (27%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACC2 | c.8690G>A p.G2897D (on ENST00000334433; = p.G975D on NM_006997.4) | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TGM1 | c.1838A>T p.H613L | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TMPRSS13 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 103/448 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.168); called by mutect2, varscan2
- TTYH3 | c.1067A>G p.N356S | Missense Mutation (SNP) | VAF 85/575 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, varscan2
- UBN1 | c.558dup p.S187Ifs*12 | Frame Shift Ins (INS) | VAF 81/297 reads (27%) | called by mutect2, pindel, varscan2
- ZNF592 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 91/407 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADGRV1 | c.17187C>T p.C5729= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as rs371639191, COSV67985868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANAPC1 | c.5103C>T p.L1701= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as rs1192098454, COSV61976026; called by muse, mutect2, varscan2
- ANKFN1 | c.837C>T p.L279= | Silent (SNP) | VAF 63/282 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP12 | c.504T>G p.V168= | Silent (SNP) | VAF 76/369 reads (21%) | called by muse, mutect2, varscan2
- BAG6 | c.429C>T p.D143= | Silent (SNP) | VAF 85/520 reads (16%) | catalogued as rs1326630859; called by muse, mutect2, varscan2
- BCOR | c.93C>T p.I31= | Silent (SNP) | VAF 60/158 reads (38%) | called by muse, mutect2, varscan2
- BPI | c.954G>A p.K318= (on ENST00000262865; = p.K314= on NM_001725.3) | Silent (SNP) | VAF 60/486 reads (12%) | catalogued as rs781554376, COSV53407465; called by muse, mutect2, varscan2
- C1orf141 | c.735C>T p.F245= | Silent (SNP) | VAF 92/232 reads (40%) | catalogued as rs267598698, COSV63992364; called by muse, mutect2, varscan2
- CCDC74B | c.784C>T p.L262= | Silent (SNP) | VAF 122/535 reads (23%) | called by muse, mutect2, varscan2
- CDH17 | c.381C>T p.L127= | Silent (SNP) | VAF 61/464 reads (13%) | called by muse, mutect2, varscan2
- CENPF | c.2388C>T p.S796= | Silent (SNP) | VAF 122/472 reads (26%) | catalogued as rs774668396; called by muse, mutect2, varscan2
- CLSTN3 | c.795C>T p.F265= | Silent (SNP) | VAF 84/349 reads (24%) | catalogued as COSV56936211; called by muse, mutect2, varscan2
- CNTRL | c.6105G>C p.V2035= | Silent (SNP) | VAF 83/363 reads (23%) | called by muse, mutect2, varscan2
- CORO1B | c.1158C>T p.D386= | Silent (SNP) | VAF 109/504 reads (22%) | catalogued as rs1444938661; called by muse, mutect2, varscan2
- CPXM1 | c.2094C>T p.F698= | Silent (SNP) | VAF 88/443 reads (20%) | catalogued as rs766761505, COSV66044544; called by muse, mutect2, varscan2
- DNER | c.1965C>T p.I655= | Silent (SNP) | VAF 95/358 reads (27%) | called by muse, mutect2, varscan2
- FLNC | c.2262C>T p.F754= | Silent (SNP) | VAF 124/393 reads (32%) | called by muse, mutect2, varscan2
- FOXA2 | c.1071C>T p.G357= (on ENST00000377115 / NM_153675.3; = p.G363= on NM_021784.5) | Silent (SNP) | VAF 94/555 reads (17%) | catalogued as rs1568715872; called by muse, mutect2, varscan2
- FRY | c.3787C>T p.L1263= | Silent (SNP) | VAF 63/275 reads (23%) | catalogued as COSV66581719; called by muse, mutect2, varscan2
- IKZF1 | c.1311G>A p.L437= | Silent (SNP) | VAF 94/581 reads (16%) | called by muse, mutect2, varscan2
- ITGA10 | c.3120G>A p.G1040= | Silent (SNP) | VAF 124/307 reads (40%) | called by muse, mutect2, varscan2
- JUN | c.541C>T p.L181= | Silent (SNP) | VAF 196/574 reads (34%) | catalogued as rs1413470255; called by muse, varscan2
- KRTAP5-4 | c.366C>T p.G122= | Silent (SNP) | VAF 52/323 reads (16%) | catalogued as COSV68788542; called by muse, mutect2
- MAB21L2 | c.462C>T p.D154= | Silent (SNP) | VAF 65/394 reads (16%) | catalogued as COSV58261269; called by muse, mutect2, varscan2
- MED13 | c.1734G>A p.R578= | Silent (SNP) | VAF 71/332 reads (21%) | called by muse, mutect2, varscan2
- MEX3A | c.489C>T p.N163= | Silent (SNP) | VAF 29/600 reads (5%) | catalogued as rs376717326; called by muse, mutect2
- NCAM1 | c.2235C>T p.F745= (on ENST00000316851 / NM_181351.5; = p.F735= on NM_000615.7) | Silent (SNP) | VAF 85/460 reads (18%) | catalogued as COSV57513390; called by muse, mutect2, varscan2
- NRK | c.306C>T p.F102= | Silent (SNP) | VAF 69/242 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1920G>A p.Q640= | Silent (SNP) | VAF 87/481 reads (18%) | catalogued as rs1353984219; called by muse, mutect2, varscan2
- PDS5A | c.3459G>A p.R1153= | Silent (SNP) | VAF 90/484 reads (19%) | called by muse, mutect2, varscan2
- PIK3CG | c.126C>T p.F42= | Silent (SNP) | VAF 94/519 reads (18%) | catalogued as COSV63245522; called by muse, mutect2, varscan2
- PKD1L1 | c.8011C>T p.L2671= | Silent (SNP) | VAF 249/605 reads (41%) | called by muse, mutect2, varscan2
- SCN10A | c.2862C>T p.S954= | Silent (SNP) | VAF 81/438 reads (18%) | catalogued as COSV101479379; called by muse, mutect2
- SEMA5B | c.2112G>A p.V704= | Silent (SNP) | VAF 113/465 reads (24%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.405G>A p.K135= | Silent (SNP) | VAF 72/432 reads (17%) | called by muse, mutect2
- TJAP1 | c.1387C>A p.R463= (on ENST00000372445 / NM_001146016.1; = p.R453= on NM_080604.3) | Silent (SNP) | VAF 42/587 reads (7%) | called by muse, mutect2
- TRANK1 | c.3243A>G p.K1081= | Silent (SNP) | VAF 120/540 reads (22%) | called by muse, mutect2
- TRPC4 | c.1080G>A p.R360= | Silent (SNP) | VAF 15/444 reads (3%) | called by muse, mutect2
- TRPC7 | c.9G>A p.R3= | Silent (SNP) | VAF 68/244 reads (28%) | catalogued as rs745955629, COSV100725747, COSV61458108; called by muse, mutect2, varscan2
- ZFX | c.1056C>A p.I352= | Silent (SNP) | VAF 76/263 reads (29%) | catalogued as COSV100457478; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1458C>G | 3'UTR (SNP) | VAF 85/353 reads (24%) | called by muse, mutect2, varscan2
- BAD | c.*143C>T | 3'UTR (SNP) | VAF 47/258 reads (18%) | catalogued as COSV99657319; called by muse, mutect2, varscan2
- BAD | c.*142C>T | 3'UTR (SNP) | VAF 48/261 reads (18%) | catalogued as rs1305734212, COSV54189042; called by muse, mutect2, varscan2
- DIRC3 | n.432C>T | RNA (SNP) | VAF 71/327 reads (22%) | called by muse, mutect2, varscan2
- HNF4A | c.1129+86C>T | Intron (SNP) | VAF 95/680 reads (14%) | called by muse, mutect2, varscan2
- MBD1 | c.*134C>A | 3'UTR (SNP) | VAF 50/710 reads (7%) | called by muse, mutect2
- PCSK6 | c.1858+1241C>T | Intron (SNP) | VAF 79/342 reads (23%) | called by muse, mutect2, varscan2
- RBM7 | chr11:114414164 C>T | 3'Flank (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
- RORA | c.196+51345C>T | Intron (SNP) | VAF 105/440 reads (24%) | called by muse, mutect2, varscan2
- SPAG11B | c.*46C>T | 3'UTR (SNP) | VAF 149/1143 reads (13%) | catalogued as rs1392225161; called by muse, mutect2, varscan2
- SPATA13 | c.-222-25297C>T | Intron (SNP) | VAF 91/420 reads (22%) | called by muse, mutect2, varscan2
- SPRR2B | c.*30G>A | 3'UTR (SNP) | VAF 282/798 reads (35%) | catalogued as rs1404627614; called by muse, mutect2, varscan2
- ZNF549 | c.199+59C>T | Intron (SNP) | VAF 184/477 reads (39%) | called by muse, mutect2, varscan2
